TARGET case TARGET-30-PARYMN — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/cf948286-cf65-513f-9d47-776545787359

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 4.4 years (1,599 days); Year of diagnosis: 2008; Days to last follow up: 1,083 days (3.0 years); INSS stage: Stage 4.
